TCGA case TCGA-KS-A4ID — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/899ed323-4fd1-4d8d-9c2f-c63d9b44e875

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 55.9 years (20,413 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,011 days (2.8 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 13; Measurement unit: Centimeters; Tumor depth measurement: 1; Tumor length measurement: 1.3; Tumor width measurement: 1.2.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Liothyronine Sodium; Days to treatment start: 1 day; Days to treatment end: 75 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Levothyroxine Sodium; Days to treatment start: 78 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant I-131 Radiation Therapy; adjuvant Radiation Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (3 entries)
- Days to follow up: 623 days (1.7 years); Disease response: Tumor Free.
- Days to follow up: 1,011 days (2.8 years); Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Hypothyroidism.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KS-A4ID-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 50 mg.
  Slide TCGA-KS-A4ID-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KS-A4ID-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KS-A4ID-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 90 mg.
  Slide TCGA-KS-A4ID-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History thyroid disease other: hypothyroidism with "nodules"; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Laterality: Right lobe; Lymph nodes examined: Yes; New tumor event diagnosis indicator: No.
- Neoplasm dimension: Tumor size width: 1.0.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: Patient did not receive I-131 treatment; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: cytomel.
- Drug treatment 2: Pharmaceutical therapy drug name: synthroid.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,011 days; disease-specific survival: no event (censored), 1,011 days; disease-free interval: no event (censored), 1,011 days; progression-free interval: no event (censored), 1,011 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KS-A4ID-01A-11D-A256-01): tumor purity 0.5, ploidy 2, whole-genome doublings 0.
